Somatic mutation profile of tumor specimen MP2PRT-PAVUXR-TMP1-A (aliquot MP2PRT-PAVUXR-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVUXR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 10.8 years (3,952 days).
Specimen MP2PRT-PAVUXR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3619501b-9147-46de-8f90-31e56a961e07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUXR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUXR-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae92ff47-94ce-4e3e-b08e-e131eceec8c4

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs200209682, COSV99445890; called by muse, mutect2, varscan2
- DDX3X | c.1058A>G p.D353G (on ENST00000399959; = p.D354G on NM_001356.5) | Missense Mutation (SNP) | VAF 92/183 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67863257, COSV67863269; called by muse, mutect2, varscan2
- MAGI1 | c.2926G>A p.G976R (on ENST00000402939 / NM_001033057.2; = p.G1004R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/461 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.125); catalogued as rs1238360124, COSV100439459, COSV100441451; called by muse, mutect2, varscan2
- NAV2 | c.1919C>A p.A640E (on ENST00000396087 / NM_001244963.2; = p.A617E on NM_145117.5) | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779400181, COSV100586483; called by muse, mutect2
- TTN | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 106/221 reads (48%) | PolyPhen benign (0.02); catalogued as rs754127089, COSV59954418; called by muse, mutect2, varscan2
- GAGE12D | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PI16 | c.1183_1185del p.S395del | In Frame Del (DEL) | VAF 120/350 reads (34%) | called by pindel, varscan2
- RXRG | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 32/371 reads (9%) | called by muse, mutect2
- WNT5A | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 19/443 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZFC3H1 | c.1886_1898delinsTGACC p.R629Lfs*3 | Frame Shift Del (DEL) | VAF 83/264 reads (31%) | called by pindel, varscan2*
- LRCH2 | c.192G>A p.P64= | Silent (SNP) | VAF 35/477 reads (7%) | called by muse, mutect2
- MYH10 | c.3282C>T p.G1094= | Silent (SNP) | VAF 127/293 reads (43%) | catalogued as rs757031791; called by muse, mutect2, varscan2
- OR8H3 | c.669T>C p.S223= | Silent (SNP) | VAF 100/291 reads (34%) | called by muse, mutect2, varscan2
- PPARGC1A | c.579G>A p.A193= | Silent (SNP) | VAF 106/265 reads (40%) | catalogued as rs574203083, COSV53533261; called by muse, mutect2, varscan2
- PROX1 | c.1242C>T p.D414= | Silent (SNP) | VAF 146/490 reads (30%) | catalogued as rs370313551; called by muse, mutect2, varscan2
- SERF2 | c.*29C>T | 3'UTR (SNP) | VAF 168/448 reads (38%) | catalogued as rs1196408347; called by muse, mutect2, varscan2
